Surgical pathology report (de-identified scan), TCGA case TCGA-BQ-5880, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BQ-5880-01A (Primary Tumor).

[page 1 of 3]
Patient Name:

Med. Rec. #:

DOB:

Gender:

Ref. Physician:

Patient Address:

Ref. Source:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

BW-5882

Clinical Diagnosis & History:

79 y/o male with left renal mass.

Specimens Submitted:

- 1: SP: Kidney, Left, Total nephrectomy:
- 2: SP: Lymph nodes, Left suprahilar and hilar and left adrenal, resection:
- 3: SP: Lymph nodes, Para-aortic, excision:

DIAGNOSIS:

1. SP: Kidney, Left, Total nephrectomy:

Tumor Type:

Renal cell carcinoma - Papillary type
Type 2

Fuhrman Nuclear Grade:

Nuclear grade III/IV

Tumor Size:

Greatest diameter is 7.5 cm.

Local Invasion (for renal cortical types):

Extends through renal capsule but confined within Gerota's fascia

Renal Vein Invasion:

Not identified

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Chronic inflammation

Adrenal Gland:

Not identified

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT3a Tumor invades the adrenal gland or perinephric tissues but not beyond Gerota's fascia

2. Lymph nodes, left suprahilar and hilar and left adrenal, resection:
- Renal cell carcinoma, papillary type involving perirenal adipose tissue.

[page 2 of 3]
- Unremarkable adrenal gland.

3. SP: Lymph nodes, Para-aortic, excision

Lymph Nodes:

Number of nodes examined: 11

Number of metastatic nodes: 6

The largest metastatic node is 3.5cm

Perinodal (extracapsular) extension identified

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT

Gross Description:

1) The specimen is received fresh labeled "left kidney" and consists of a kidney with attached ureter, renal vessels and perinephric fat weighing 285 g in total. The kidney measures 10.0 x 6.5 x 4.5 cm. The attached ureter measures 2.5 cm in length and 0.5 cm in diameter. The attached renal vein measures 0.8 cm in length and 0.7 cm in diameter. The renal vessels and ureter margins are grossly unremarkable. An adrenal gland is not identified grossly. The kidney is inked black and bivalved to reveal an ill-defined bright-yellow tumor, located at mid portion of kidney and protruding out and involving the perinephric fat, measuring 7.5 x 5.5 x 5.0 cm. Sections through the remainder of the kidney reveal a pink brown parenchyma, with a well-defined cortico-medullary junction. The cortex measures 1.0 cm and the calyces appear normal. No lymph nodes are identified in the perinephric fat. Representative sections are submitted for TPS and for permanent sections.

Summary of sections:

UVM -- ureteral and vessel margins

T -- tumor

THF -- tumor with hilar fat

TSF -- tumor with sinus fat

TK -- tumor with adjacent kidney

RP -- renal pelvis representative sections

K -- representative sections kidney

F-hilar fat

2) The specimen is received fresh labeled "Left suprarenal, and hilar lymph node and left adrenal". It consists of a segment of yellow-tan fatty lobular tissue containing the adrenal gland and adjacent encapsulated, seemingly intact red-brown mass. The overall dimensions of the specimen are 14.5 x 5 x 3 cm. The adrenal measures 4.5 x 1.2 x 1.0 cm, and on cut section shows unremarkable yellow orange appearance. The red-brown mass measures 4 x 4 x 3 cm, is located directly adjacent to the adrenal gland, but does not show any definite involvement of the gland. The outer surface of the mass is inked black. On cut section of the mass, it shows cystic, markedly friable dark red hemorrhagic appearance filled with hemorrhagic material. No lymph nodes are grossly identified. Representative sections are submitted. A sample of the mass is given to TPS. The specimen has been photographed.

Summary of sections:

ADR-adrenal

M-Mass

ADRM-adrenal and mass

3). The specimen is received in formalin labeled "Para-aortic lymph nodes". It consists of multiple lymph nodes ranging from 0.3 x 0.3 cm up to 3.5 x 2.5 cm in greatest dimensions. Cut section of one of the largest lymph nodes shows mottled yellow orange to

[page 3 of 3]
black appearance. Representative sections of this and one of the lymph node are submitted. The largest lymph node is quadrisectioned to show predominantly yellow-tan fatty lobular appearance with focal firm white-tan areas. After the largest lymph node is quadrisectioned, each of the sections is bisected. The remainder of the lymph nodes are entirely submitted.

Summary of sections:

A-section of largest lymph node, bisected
B-section of largest lymph node, bisected
C-section of largest lymph node, bisected
D-section of largest lymph node, bisected
RS1-representative sections of one of the largest lymph nodes
RS2- representative section of one of the largest lymph nodes, bisected
LN - lymph nodes
BLN1 - bisected lymph node 1
BLN2 - bisected lymph node 2
BLN3 - bisected lymph node 3

Summary of Sections:

Part 1: SP: Kidney, Left, Total nephrectomy: [REDACTED]

Block	Sect. Site	PCs
1	f	1
1	k	1
1	rp	1
5	t	5
1	thf	1
1	tk	1
1	tsf	1
1	uvm	1

Part 2: SP: Lymph nodes, Left suprahilar and hilar and left adrenal, resection [REDACTED]

Block	Sect. Site	PCs
3	adr	3
1	adrm	1
5	m	5

Part 3: SP: Lymph nodes, Para-aortic, excision [REDACTED]

Block	Sect. Site	PCs
2	a	2
2	b	2
1	bln1	1
1	bln2	1
1	bln3	1
2	c	2
2	d	2
1	ln	1
2	rs1	2
2	rs2	2

Source: NCI Genomic Data Commons file a3f9d408-36ce-4713-ac0d-1836565fb0a2 (TCGA-BQ-5880.4E539A50-675D-401E-9138-EFB5B9111D01.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).